Somatic mutation profile of tumor specimen TCGA-TS-A8AI-01A (aliquot TCGA-TS-A8AI-01A-11D-A39R-32) from TCGA case TCGA-TS-A8AI, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.4 years (21,323 days).
Specimen TCGA-TS-A8AI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 751049a2-81ee-453a-8702-4377abe17ec1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A8AI-10A (Blood Derived Normal), aliquot TCGA-TS-A8AI-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fd1e0b4-d657-496a-beea-9b61bfd24381

The open-access MAF lists 36 somatic variants for this specimen: 22 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 11, Nonsense Mutation 3, Intron 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT4 | c.14419A>G p.I4807V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as COSV58687902; called by muse, mutect2, varscan2
- MATN4 | c.1474C>T p.R492C (on ENST00000372754; = p.R451C on NM_003833.4) | Missense Mutation (SNP) | VAF 37/140 reads (26%) | PolyPhen probably damaging (0.987); catalogued as rs778298691, COSV61350538; called by muse, mutect2, varscan2
- OR5D14 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs1368458918, COSV100162250; called by muse, mutect2, varscan2
- SCN11A | c.4477T>C p.S1493P | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56573083; called by muse, mutect2, varscan2
- SRGAP3 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100840761; called by muse, mutect2
- SYMPK | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs367969885; called by muse, mutect2, varscan2
- TCHHL1 | c.2203C>A p.Q735K | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1557800870; called by muse, mutect2, varscan2
- TRABD2A | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs775825438, COSV59103728; called by muse, mutect2, varscan2
- ANKRD26 | c.2537C>T p.T846I | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DHX38 | c.3270C>A p.Y1090* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- LPIN2 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- MDN1 | c.1915G>T p.E639* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- PDE10A | c.1417G>T p.E473* | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- SEC23A | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SGIP1 | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SORCS1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- SUPT20H | c.1539_1542del p.N513Kfs*36 (on ENST00000350612 / NM_001014286.3; = p.N514Kfs*36 on NM_017569.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | called by pindel, varscan2
- TM9SF2 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- VAV2 | c.112C>G p.R38G | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VEPH1 | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF440 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZSCAN21 | c.1312C>A p.H438N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACADVL | c.117C>G p.P39= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- ARAP3 | c.294C>T p.P98= | Silent (SNP) | VAF 42/180 reads (23%) | catalogued as rs751979295; called by muse, mutect2, varscan2
- CEP162 | c.9C>T p.N3= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- FAM124B | c.453C>T p.D151= | Silent (SNP) | VAF 43/165 reads (26%) | catalogued as rs755464550, COSV66271682; called by muse, mutect2, varscan2
- FGR | c.774C>T p.I258= | Silent (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- GPRIN1 | c.2241C>T p.R747= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV56137947; called by muse, mutect2, varscan2
- H4C3 | c.129C>G p.G43= | Silent (SNP) | VAF 40/101 reads (40%) | called by muse, mutect2, varscan2
- KAT14 | c.927G>T p.V309= | Silent (SNP) | VAF 63/213 reads (30%) | called by muse, mutect2, varscan2
- MAPK7 | c.480C>G p.R160= | Silent (SNP) | VAF 34/120 reads (28%) | called by muse, mutect2, varscan2
- PHETA1 | c.57C>T p.D19= | Silent (SNP) | VAF 36/139 reads (26%) | called by muse, mutect2, varscan2
- TNXB | c.8508C>T p.H2836= (on ENST00000647633; = p.H2589= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- AL590867.2 | n.15G>A | RNA (SNP) | VAF 35/113 reads (31%) | called by muse, mutect2, varscan2
- ANKMY1 | c.-122+565C>G | Intron (SNP) | VAF 45/166 reads (27%) | called by muse, mutect2, varscan2
- TGFB2 | c.346+16338C>T | Intron (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100860452; called by muse, mutect2, varscan2
